Somatic mutation profile of tumor specimen TCGA-77-6843-01A (aliquot TCGA-77-6843-01A-11D-1945-08) from TCGA case TCGA-77-6843, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.7 years (27,291 days).
Specimen TCGA-77-6843-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4399f90-5a32-4fcb-ae14-cf61e6872de0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-6843-10A (Blood Derived Normal), aliquot TCGA-77-6843-10A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a661dd0-1378-4710-beb9-636371fd7de6

The open-access MAF lists 185 somatic variants for this specimen: 145 protein-altering or splice-affecting, 39 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 39, Nonsense Mutation 10, Splice Site 6, In Frame Del 4, Splice Region 3, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 41/110 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 141/191 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- A2M | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV104404302; called by muse, mutect2, varscan2
- ABCB5 | c.2954C>A p.A985D (on ENST00000404938 / NM_001163941.2; = p.A540D on NM_178559.6) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1247650249; called by muse, mutect2, varscan2
- ACTN3 | c.2408G>A p.R803H | Missense Mutation (SNP) | VAF 40/605 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs758580966, COSV59750770, COSV59750906; called by muse, mutect2
- ADPRHL1 | c.669C>A p.Y223* | Nonsense Mutation (SNP) | VAF 6/150 reads (4%) | catalogued as COSV100733470; called by muse, mutect2
- AHNAK | c.12211C>G p.P4071A | Missense Mutation (SNP) | VAF 220/670 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs763980510; called by muse, mutect2, varscan2
- AKAP13 | c.6598C>T p.R2200C (on ENST00000394518 / NM_007200.5; = p.R2204C on NM_006738.6) | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63450117; called by muse, mutect2, varscan2
- ANAPC4 | c.1398A>C p.K466N | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as COSV59544065; called by muse, mutect2, varscan2
- APBB1IP | c.1532C>G p.A511G | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.034); catalogued as COSV66130590; called by muse, mutect2, varscan2
- C7orf61 | c.378C>A p.C126* | Nonsense Mutation (SNP) | VAF 22/327 reads (7%) | catalogued as COSV100190311; called by muse, mutect2
- CC2D1A | c.2316+2T>A p.X772_splice | Splice Site (SNP) | VAF 61/165 reads (37%) | catalogued as COSV100528570; called by muse, mutect2, varscan2
- CKAP5 | c.2863-1G>C p.X955_splice | Splice Site (SNP) | VAF 39/101 reads (39%) | catalogued as COSV100370981; called by muse, mutect2, varscan2
- COPS2 | c.1177A>G p.I393V | Missense Mutation (SNP) | VAF 105/282 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.246); catalogued as COSV54647526; called by muse, mutect2, varscan2
- CYP26B1 | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50014959; called by muse, mutect2, varscan2
- CYP2C9 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 92/186 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV53247443; called by muse, mutect2, varscan2
- DNAH11 | c.7847A>G p.H2616R | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs750580632; called by muse, mutect2, varscan2
- DNAH5 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 85/323 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54223750; called by muse, mutect2, varscan2
- DNAH7 | c.7634C>A p.S2545Y | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56759625; called by muse, mutect2, varscan2
- DOK5 | c.767C>A p.S256* | Nonsense Mutation (SNP) | VAF 40/105 reads (38%) | catalogued as COSV52820332, COSV52823256; called by muse, mutect2, varscan2
- DPY19L3 | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1222339896; called by muse, mutect2, varscan2
- DTNA | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs954418044, COSV51998737; called by muse, mutect2, varscan2
- ECHDC3 | c.586A>G p.R196G | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1325383596; called by muse, mutect2, varscan2
- EPHA8 | c.1084T>G p.Y362D | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV51293908; called by muse, mutect2, varscan2
- FAM135A | c.3098T>C p.I1033T (on ENST00000370479 / NM_001351599.1; = p.I820T on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs201882246; called by muse, mutect2, varscan2
- FAM169A | c.1769C>A p.S590Y | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57187531; called by muse, mutect2, varscan2
- FAT2 | c.6902C>G p.S2301* | Nonsense Mutation (SNP) | VAF 10/288 reads (3%) | catalogued as COSV99943462; called by muse, mutect2
- FBXO27 | c.635A>G p.N212S | Missense Mutation (SNP) | VAF 233/650 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs777232845; called by muse, mutect2, varscan2
- FCGBP | c.8042C>T p.P2681L | Missense Mutation (SNP) | VAF 116/1185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99662987; called by muse, mutect2, varscan2
- FUT8 | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.662); catalogued as COSV100651498; called by muse, mutect2
- GBP1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 190/581 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs372549555; called by muse, mutect2, varscan2
- GRIN1 | c.1310C>G p.T437S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV100160478; called by muse, mutect2
- GTF2F1 | c.308A>G p.N103S | Missense Mutation (SNP) | VAF 105/291 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs201622118; called by muse, mutect2, varscan2
- HERC2 | c.2682G>C p.W894C | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99875047; called by muse, mutect2
- HS3ST3A1 | c.700A>G p.K234E | Missense Mutation (SNP) | VAF 107/197 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.314); catalogued as COSV99404398; called by muse, mutect2, varscan2
- KCNS1 | c.529G>T p.V177L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV60259478; called by muse, mutect2, varscan2
- KIAA1549L | c.2308C>T p.R770C (on ENST00000321505; = p.R1067C on NM_012194.3) | Missense Mutation (SNP) | VAF 121/357 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as rs368053850; called by muse, mutect2, varscan2
- LAMA4 | c.1078-1G>C p.X360_splice (on ENST00000230538 / NM_001105206.3; = p.X353_splice on NM_002290.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/103 reads (8%) | catalogued as COSV100038806; called by muse, mutect2
- LONP2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 95/307 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); catalogued as rs776336728, COSV53523959; called by muse, mutect2, varscan2
- LY6G6D | c.178+1G>A p.X60_splice | Splice Site (SNP) | VAF 29/95 reads (31%) | catalogued as rs769646744, COSV101010836; called by muse, mutect2, varscan2
- MAGEC3 | c.1047A>C p.Q349H | Missense Mutation (SNP) | VAF 87/120 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV100025118; called by muse, mutect2, varscan2
- MAGEC3 | c.1048G>T p.G350* | Nonsense Mutation (SNP) | VAF 86/117 reads (74%) | catalogued as COSV53578313, COSV53578613; called by muse, mutect2, varscan2
- MBP | c.784G>A p.G262R (on ENST00000355994 / NM_001025101.2; = p.G144R on NM_002385.3) | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs759020235, COSV62828439; called by muse, mutect2, varscan2
- MMP17 | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); catalogued as rs376422502, COSV99053584; called by muse, mutect2, varscan2
- MSH3 | c.1654-1G>T p.X552_splice | Splice Site (SNP) | VAF 24/72 reads (33%) | catalogued as COSV54166838, COSV99434545; called by muse, mutect2, varscan2
- MX2 | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 5/109 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100416025; called by muse, mutect2
- MYLK | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 121/454 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs532659627, COSV60611222, COSV60615080, COSV60623949; called by muse, mutect2, varscan2
- NBEAL1 | c.6378-1G>C p.X2126_splice | Splice Site (SNP) | VAF 63/216 reads (29%) | catalogued as rs906313308, COSV101355561; called by muse, mutect2, varscan2
- OR2T2 | c.161C>A p.S54Y | Missense Mutation (SNP) | VAF 195/499 reads (39%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.707); catalogued as rs201768488, COSV61617741, COSV61618192; called by muse, mutect2, varscan2
- PDE3A | c.1697C>G p.T566S | Missense Mutation (SNP) | VAF 28/500 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as COSV100762422; called by muse, mutect2
- PTGIS | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs150077993, COSV54841385; called by muse, mutect2, varscan2
- RAX | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.204); catalogued as rs1376153990; called by muse, mutect2, varscan2
- SKIL | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 115/752 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1054285814, COSV99378532; called by muse, mutect2, varscan2
- SLC52A2 | c.83A>G p.N28S | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs141698844; ClinVar: uncertain significance; called by muse, varscan2
- SLC5A3 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 77/225 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.121); catalogued as COSV62969407; called by muse, mutect2, varscan2
- SNCB | c.334A>G p.M112V | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV59527828; called by muse, varscan2
- SRGAP2 | c.1467G>A p.R489= (on ENST00000624873 / NM_001170637.4; = p.R490= on NM_015326.5 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 52/70 reads (74%) | catalogued as rs782573262; called by muse, mutect2, varscan2
- TAF1L | c.3181G>C p.G1061R | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.184); catalogued as COSV99644964; called by muse, mutect2
- TATDN2 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 116/251 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.446); catalogued as rs755375723; called by muse, mutect2, varscan2
- TRIM31 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 20/528 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV65060305; called by muse, mutect2
- UBN1 | c.2848G>A p.V950I | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs557466285, COSV52165779; called by muse, mutect2, varscan2
- USH2A | c.14792T>C p.L4931S | Missense Mutation (SNP) | VAF 101/244 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1461313296; called by muse, mutect2, varscan2
- USH2A | c.10058C>A p.P3353Q | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV56389189; called by muse, mutect2, varscan2
- USH2A | c.6874C>T p.R2292C | Missense Mutation (SNP) | VAF 226/296 reads (76%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as rs727503722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VAMP7 | c.254G>A p.R85K | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV99387915; called by muse, mutect2
- WDR72 | c.2391G>T p.L797F | Missense Mutation (SNP) | VAF 136/435 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs143898711; called by muse, mutect2, varscan2
- ZNF521 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.826); catalogued as rs140546909; called by muse, mutect2, varscan2
- AGRN | c.1969G>T p.E657* | Nonsense Mutation (SNP) | VAF 18/28 reads (64%) | called by muse, varscan2
- ANAPC15 | c.123C>G p.L41= | Splice Region (SNP) | VAF 16/136 reads (12%) | called by muse, varscan2
- ANKMY1 | c.664C>A p.Q222K | Missense Mutation (SNP) | VAF 95/275 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- ATP10D | c.3949T>C p.Y1317H | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ATP2C1 | c.1159A>T p.I387F | Missense Mutation (SNP) | VAF 167/735 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP8A2 | c.3241G>C p.A1081P | Missense Mutation (SNP) | VAF 76/258 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- BRCA2 | c.1187C>G p.S396C | Missense Mutation (SNP) | VAF 206/539 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CALHM5 | c.464A>G p.K155R | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CASR | c.535C>A p.Q179K | Missense Mutation (SNP) | VAF 145/564 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CDKN2A | c.326_343del p.A109_P114del | In Frame Del (DEL) | VAF 20/57 reads (35%) | called by mutect2, pindel, varscan2
- CFAP47 | c.607_615del p.K203_D205del | In Frame Del (DEL) | VAF 27/126 reads (21%) | called by mutect2, pindel, varscan2
- CNTNAP4 | c.1756C>T p.H586Y | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COBLL1 | c.3301C>A p.H1101N (on ENST00000392717; = p.H1063N on NM_014900.5) | Missense Mutation (SNP) | VAF 80/199 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL8A1 | c.1755del p.P586Qfs*10 | Frame Shift Del (DEL) | VAF 47/134 reads (35%) | called by mutect2, pindel*, varscan2
- CORIN | c.2081T>C p.I694T | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DGKH | c.2424T>A p.Y808* | Nonsense Mutation (SNP) | VAF 42/135 reads (31%) | called by muse, mutect2, varscan2
- DIDO1 | c.6236G>A p.R2079K | Missense Mutation (SNP) | VAF 172/544 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- DIP2C | c.1544C>G p.T515S | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DYRK1B | c.504G>T p.E168D | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- E4F1 | c.1543G>C p.D515H | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENOSF1 | c.456T>C p.I152= (on ENST00000340116 / NM_001354066.2; = p.I104= on NM_017512.7 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2, varscan2
- F8 | c.1927A>G p.S643G | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM160A2 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 44/106 reads (42%) | called by muse, mutect2, varscan2
- FBN2 | c.3316C>A p.L1106I | Missense Mutation (SNP) | VAF 93/280 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FIG4 | c.2513C>G p.P838R | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLI2 | c.4420C>G p.P1474A (on ENST00000361492 / NM_001374353.1; = p.P1491A on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/240 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR156 | c.2241G>T p.E747D | Missense Mutation (SNP) | VAF 123/409 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GPR4 | c.1027_1047delinsCTCCCA p.A343_Q349delinsLP | In Frame Del (DEL) | VAF 57/202 reads (28%) | called by pindel, varscan2*
- GRIN2D | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 192/755 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HERC1 | c.3908T>C p.V1303A | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- HERC6 | c.1642C>A p.H548N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV1-36 | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- KRT36 | c.475T>C p.S159P | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- LYST | c.743G>T p.S248I | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- MAGEA6 | c.542G>T p.C181F | Missense Mutation (SNP) | VAF 139/206 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MAGT1 | c.98A>C p.K33T (on ENST00000618282 / NM_001367916.1; = p.K65T on NM_032121.5) | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- MDM1 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- MMP16 | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 91/318 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- MYBPC2 | c.703A>G p.I235V | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- NACC2 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.61); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- NBEA | c.425C>A p.A142D | Missense Mutation (SNP) | VAF 77/239 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NFIB | c.204C>G p.I68M | Missense Mutation (SNP) | VAF 77/146 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- NPAP1 | c.2165C>A p.P722Q | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- NR2F2 | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10AG1 | c.864_866del p.I288del | In Frame Del (DEL) | VAF 40/154 reads (26%) | called by mutect2, pindel, varscan2
- OR2W1 | c.648A>G p.I216M | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- OR4K5 | c.927G>C p.R309S | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR5K2 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 196/781 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR6F1 | c.382T>C p.Y128H | Missense Mutation (SNP) | VAF 160/203 reads (79%) | SIFT tolerated (0.56); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- OTUD7A | c.1774G>C p.E592Q (on ENST00000307050 / NM_001382637.1; = p.E585Q on NM_130901.3) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDHB10 | c.2329C>G p.Q777E | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PCDHGA12 | c.1646G>T p.S549I | Missense Mutation (SNP) | VAF 206/601 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PKHD1L1 | c.11875G>C p.V3959L | Missense Mutation (SNP) | VAF 108/317 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PPARGC1A | c.1927G>T p.E643* | Nonsense Mutation (SNP) | VAF 103/317 reads (32%) | called by muse, mutect2, varscan2
- PPP2CA | c.466A>G p.T156A | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRDM5 | c.1591G>T p.G531* | Nonsense Mutation (SNP) | VAF 47/80 reads (59%) | called by muse, mutect2, varscan2
- PRICKLE1 | c.1344G>T p.M448I | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RFX1 | c.2573C>G p.S858C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RLF | c.3161C>A p.P1054H | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- ROCK2 | c.3215C>G p.S1072C | Missense Mutation (SNP) | VAF 15/286 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); called by muse, mutect2
- SDCCAG8 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 140/259 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- SIGIRR | c.773T>A p.F258Y | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- SLAIN2 | c.1564A>T p.T522S | Missense Mutation (SNP) | VAF 113/340 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.306); called by mutect2, varscan2
- SLC12A5 | c.2738T>A p.V913E (on ENST00000454036 / NM_001134771.2; = p.V890E on NM_020708.5) | Missense Mutation (SNP) | VAF 11/281 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- SLFN5 | c.554A>G p.E185G | Missense Mutation (SNP) | VAF 101/277 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SNCB | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); called by muse, varscan2
- STOX2 | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- TCN2 | c.718T>C p.F240L | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- TMEM131 | c.1103C>G p.A368G | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- TMTC2 | c.731A>G p.Y244C | Missense Mutation (SNP) | VAF 130/407 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- TRIM32 | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPC1 | c.2215G>C p.V739L (on ENST00000476941 / NM_001251845.2; = p.V705L on NM_003304.4) | Missense Mutation (SNP) | VAF 69/269 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- UGT2B15 | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 84/289 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- USH2A | c.8449C>G p.H2817D | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USP33 | c.2822C>G p.S941C | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VCAN | c.7846A>G p.S2616G | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VIRMA | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- VPS13C | c.10718T>A p.M3573K (on ENST00000644861 / NM_020821.3; = p.M3530K on NM_017684.5) | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ADAMTS12 | c.3696G>A p.G1232= | Silent (SNP) | VAF 93/298 reads (31%) | catalogued as rs780010676, COSV61259334; called by muse, mutect2, varscan2
- CORO1B | c.228G>T p.P76= | Silent (SNP) | VAF 37/107 reads (35%) | catalogued as COSV58171815; called by muse, mutect2, varscan2
- CYP2E1 | c.543C>T p.A181= | Silent (SNP) | VAF 81/251 reads (32%) | catalogued as rs79549556; called by muse, mutect2, varscan2
- DCC | c.708G>A p.L236= | Silent (SNP) | VAF 61/151 reads (40%) | called by muse, mutect2, varscan2
- DIDO1 | c.6120C>G p.R2040= | Silent (SNP) | VAF 48/163 reads (29%) | called by muse, mutect2, varscan2
- EMILIN2 | c.1767G>T p.T589= | Silent (SNP) | VAF 38/110 reads (35%) | catalogued as COSV54423839; called by muse, mutect2, varscan2
- F13B | c.1800T>C p.F600= | Silent (SNP) | VAF 88/113 reads (78%) | called by muse, mutect2, varscan2
- FSIP1 | c.99G>A p.V33= | Silent (SNP) | VAF 68/207 reads (33%) | catalogued as rs183248261; called by muse, mutect2, varscan2
- GLRA3 | c.1035A>G p.K345= | Silent (SNP) | VAF 47/99 reads (47%) | called by muse, mutect2, varscan2
- JAKMIP2 | c.465A>G p.E155= | Silent (SNP) | VAF 161/446 reads (36%) | catalogued as rs1355019171; called by muse, mutect2, varscan2
- KCNN3 | c.1362C>G p.L454= | Silent (SNP) | VAF 66/245 reads (27%) | catalogued as rs1557967941, COSV55219243; called by muse, mutect2, varscan2
- KLHL32 | c.834G>A p.Q278= | Silent (SNP) | VAF 14/146 reads (10%) | catalogued as COSV100987400; called by muse, mutect2, varscan2
- LAMB1 | c.5172T>C p.N1724= | Silent (SNP) | VAF 57/163 reads (35%) | catalogued as COSV52739956; called by muse, mutect2, varscan2
- LRRC17 | c.780A>G p.K260= | Silent (SNP) | VAF 50/159 reads (31%) | called by muse, mutect2, varscan2
- LSAMP | c.825G>A p.L275= | Silent (SNP) | VAF 11/256 reads (4%) | catalogued as COSV100371573; called by muse, mutect2
- MARCHF6 | c.1002C>T p.I334= | Silent (SNP) | VAF 19/147 reads (13%) | called by muse, mutect2, varscan2
- MS4A3 | c.234C>T p.F78= | Silent (SNP) | VAF 86/240 reads (36%) | called by muse, mutect2, varscan2
- MUC16 | c.31548C>A p.A10516= | Silent (SNP) | VAF 348/1023 reads (34%) | catalogued as rs1276976193; called by muse, mutect2, varscan2
- NUDCD3 | c.1011T>C p.A337= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as rs750784074; called by muse, mutect2, varscan2
- OR7G1 | c.579C>G p.L193= | Silent (SNP) | VAF 10/234 reads (4%) | catalogued as COSV99528658; called by muse, mutect2
- PCOLCE2 | c.966T>C p.V322= | Silent (SNP) | VAF 33/119 reads (28%) | called by muse, mutect2, varscan2
- PGA5 | c.1011C>T p.I337= | Silent (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- PKP3 | c.1164C>A p.L388= | Silent (SNP) | VAF 38/125 reads (30%) | called by muse, mutect2, varscan2
- RARS1 | c.150A>G p.K50= | Silent (SNP) | VAF 47/121 reads (39%) | catalogued as rs754458167; called by muse, mutect2, varscan2
- RNF17 | c.258C>T p.Y86= | Silent (SNP) | VAF 25/106 reads (24%) | called by muse, mutect2, varscan2
- SAMD5 | c.165C>A p.I55= | Silent (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- SART1 | c.1299G>T p.G433= | Silent (SNP) | VAF 115/466 reads (25%) | called by muse, mutect2, varscan2
- SLC35A1 | c.168A>G p.L56= | Silent (SNP) | VAF 76/199 reads (38%) | called by muse, mutect2, varscan2
- SNCB | c.333G>C p.L111= | Silent (SNP) | VAF 28/80 reads (35%) | called by muse, varscan2
- SPDL1 | c.1536C>G p.V512= | Silent (SNP) | VAF 13/182 reads (7%) | catalogued as COSV99517627; called by muse, mutect2
- SPTA1 | c.4422G>C p.R1474= | Silent (SNP) | VAF 110/219 reads (50%) | called by muse, mutect2, varscan2
- SYNE1 | c.18726C>A p.A6242= (on ENST00000367255 / NM_182961.4; = p.A6171= on NM_033071.3) | Silent (SNP) | VAF 66/186 reads (35%) | catalogued as rs769736021; called by muse, mutect2, varscan2
- SYNE3 | c.1179C>T p.D393= | Silent (SNP) | VAF 59/103 reads (57%) | catalogued as rs974926887; called by muse, mutect2, varscan2
- TBC1D4 | c.1326C>G p.A442= | Silent (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2
- TBX18 | c.1068C>T p.T356= | Silent (SNP) | VAF 142/441 reads (32%) | called by muse, mutect2, varscan2
- THBS3 | c.2361T>G p.T787= | Silent (SNP) | VAF 120/221 reads (54%) | called by muse, mutect2, varscan2
- TMEM132B | c.1428C>G p.S476= | Silent (SNP) | VAF 34/115 reads (30%) | called by muse, mutect2, varscan2
- TTN | c.78621T>C p.I26207= (on ENST00000591111; = p.I18783= on NM_003319.4) | Silent (SNP) | VAF 68/219 reads (31%) | called by muse, mutect2, varscan2
- ZNF407 | c.1197A>G p.K399= | Silent (SNP) | VAF 34/103 reads (33%) | called by muse, mutect2, varscan2
- EPSTI1 | chr13:42888441 C>G | 3'Flank (SNP) | VAF 11/234 reads (5%) | catalogued as COSV100553044; called by muse, mutect2
